Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7178, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7178-01A (Primary Tumor).

[page 1 of 3]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (K) MANDIBLE:
SQUAMOUS CELL CARCINOMA INVOLVING MANDIBLE.
TUMOR ABUTTING ANTERIOR MANDIBLE MARGIN.
TUMOR WITHIN 2 MM OF POSTERIOR MARGIN.
- [REDACTED]

Entire report and diagnosis completed by: [REDACTED]

DIAGNOSIS

- (A) LEFT NECK DISSECTION LEVEL I:
METASTATIC SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED IN
1 OUT OF 5 LYMPH NODES.
Salivary gland, no tumor present.
- (B) LEVEL I, II, III AND V:
METASTATIC SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED IN 3 OUT
OF 16 LYMPH NODES.
(1/4 LEVEL I; 1/3 LEVEL II; 0/5 LEVEL III; 1/4 LEVEL 5).
Salivary gland, no tumor present.
- (C) MEDULLARY CAVITY:
Bone with myxoid change, no tumor present.
- (D) ANTERIOR FLOOR OF MOUTH:
Squamous mucosa, no tumor present.
- (E) RIGHT LATERAL FLOOR OF MOUTH:
Squamous mucosa, no tumor present.
- (F) RIGHT ANTERIOR TONSILLAR PILLAR:
Squamous mucosa, no tumor present.
- (G) RETROMOLAR TRIGONE:
Squamous mucosa, no tumor present.
- (H) BUCCAL MUCOSA:
Squamous mucosa, no tumor present.
- (I) LABIAL MUCOSA:
Squamous mucosa, no tumor present.
- (J) RIGHT MEDIAL PTERYGOID:
Squamous mucosa, no tumor present.
- (K) MANDIBLE:
POORLY TO MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, DEEPLY
INVASIVE.
Mandible pending decalcification.

[page 2 of 3]
Entire report and diagnosis completed by:

GROSS DESCRIPTION

(A) LEFT NECK DISSECTION, LEVEL 1 - Pink-tan tissue segment (6.3 x 4.0 x 1.2 cm). Several lymph nodes are identified. One grossly positive lymph node is identified which measures up to 1.5 cm in greatest dimension. The salivary gland is unremarkable.

SECTION CODE: A1, one bisected lymph node; A2, two lymph nodes; A3, portion of grossly positive lymph node; A4, one lymph node; A5, representative salivary gland.

(B) LEVEL 5 - An irregular fragment of fibroadipose tissue with multiple lymph nodes (overall 3.0 x 2.5 x 1.0 cm). Four lymph nodes are identified. Entire specimen is submitted.

LEVEL 3 - An irregular fragment of fibroadipose tissue (2.7 x 1.5 x 1.0 cm). At least two lymph nodes are identified (1.7 and 0.8 cm).

LEVEL 1 - A portion of salivary gland, fibroadipose tissue, and lymph node (overall 3.5 x 3.5 x 2.8 cm). The salivary gland (3.4 cm) has an unremarkable, lobulated, tan-yellow cut surface. Multiple lymph nodes are identified and entirely submitted.

LEVEL 2 - An irregular fragment of fibroadipose tissue (3.8 x 2.9 x 2.0 cm). Multiple lymph nodes are identified. One lymph node (1.6 cm) is grossly positive. Representative tissue of that specimen is submitted for research.

SECTION CODE: Level 5, B1, four lymph nodes; B2, remainder of tissue; level 3, B3, two lymph nodes; B4, remainder of tissue; level 1, B5, salivary gland; B6, three lymph nodes; B7, one lymph node (grossly positive); level 2, B8, representative sections of grossly positive lymph nodes; B9, four possible lymph nodes.

(C) MEDULLARY CAVITY - Irregular fragments of red-brown soft tissue admixed with tiny speckles of bone, 0.6 x 0.4 x 0.1 cm. Submitted in toto in C.

*FS/DX: BONE WITH MYXOID CHANGE, NO TUMOR PRESENT.

(D) ANTERIOR FLOOR OF MOUTH - A strip of pale pink mucosa (2.1 x 0.2 x 0.2 cm). In toto in D.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(E) RIGHT LATERAL FLOOR OF MOUTH - A strip of pale pink mucosa (3.4 x 0.1 x 0.1 cm). In toto in E for frozen section.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(F) RIGHT ANTERIOR TONSTIL PILLAR - A strip of pale pink mucosa, 1.7 x 0.1 x 0.1 cm. In toto in F.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(G) RETROMOLAR TRIGONE - A strip of pale pink mucosa (1.8 x 0.2 x 0.1 cm). In toto in G for frozen section.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(H) BUCCAL MUCOSA - A strip of pale pink mucosa (2.2 x 0.3 x 0.2 cm). In toto in H.

[page 3 of 3]
[REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(I) LABIAL MUCOSA - A strip of pale pink mucosa (1.8 x 0.2 x 0.1 cm). In toto in I. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(J) RIGHT MEDIAL PTERYGOID - Red-brown soft tissue (0.3 x 0.2 x 0.2 cm). In toto in J for frozen section. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(K) MANDIBLE - A portion of mandible and attached soft tissue and skin with overall measurements of 10 x 5.0 x 5.0 cm, and ulcerated friable and soft tissue mass on the inferior aspect of the gum measuring 6.0 x 1.5 x 2.0 cm. The mucosa itself and the soft tissue margin of resection appear grossly uninvolved. There is a gross bony involvement on the posterior aspect of the right jaw and center of the specimen. The tumor also extends through the soft tissue. The anterior aspect of the mandible forms a large firm nodule beneath the skin. The nodule measures 3.3 cm. The specimen represents sequentially from right to left from K1 to K16. [REDACTED]

SNOMED CODES

M-80703 T-51800

Source: NCI Genomic Data Commons file c47cb4cf-22e1-4982-a5e7-51b247fe371d (TCGA-CV-7178.42CAC0F3-C653-48E6-A4E1-4D6A580ACEFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).